Gene-level copy-number profile of tumor specimen TCGA-06-0122-01A from TCGA case TCGA-06-0122, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 84.8 years (30,968 days).
Specimen TCGA-06-0122-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.0674a285-6af2-4476-b50f-92a437b052b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0122-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3b1903a9-d7c8-4e50-afc4-2fbb857d2952

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 5,369; copy number 2: 47,864; copy number 3: 6,347; copy number 4: 179; copy number 24: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0122-01A-01D-0214-01): tumor purity 0.73, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,824,213, 14 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,721,724–56,000,181, 37 genes, copy number 24 (within-gene range 4–24): AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17.

Autosomal genes at a single copy (total copy number 1): 5,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
